MMRF case MMRF_2152 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d81a6c52-6b59-4bd6-b5b1-a22093b0f051

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.1 years (19,409 days); ISS stage: III; Days to last known disease status: 64 days; Days to last follow up: 64 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 0): M Protein 0.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 989 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.58 g/L; Beta 2 Microglobulin 10.8 µg/mL; Lactate Dehydrogenase 6.82 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 327 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 4.68 mmol/L.
- Day 64 (ECOG 0): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Immunoglobulin G 8.68 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.64 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 332 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 1.75 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.

Other clinical attributes
- Day -10: Weight: 57 kg; Height: 152 cm.

Biospecimens (2 samples)
- Sample MMRF_2152_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_2152_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
